Somatic mutation profile of tumor specimen MP2PRT-PARGNS-TMP1-A (aliquot MP2PRT-PARGNS-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARGNS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,547 days).
Specimen MP2PRT-PARGNS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba25f43e-5f66-4b89-8937-52a6e3238265.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARGNS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARGNS-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99453c37-f0a6-40aa-acb7-4ffbbf5a3193

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Del 3, Silent 1, Nonsense Mutation 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN4 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 22/578 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.174); catalogued as rs1473207701; called by muse, mutect2
- EWSR1 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 35/419 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs535564625, COSV58422816; called by muse, mutect2
- LRRC7 | c.3334A>G p.R1112G (on ENST00000651989 / NM_001370785.2; = p.R1079G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs745554902; called by muse, mutect2, varscan2
- RAPGEF6 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 101/229 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199588545; called by muse, mutect2, varscan2
- STEAP2 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 30/331 reads (9%) | catalogued as rs759069761, COSV55291911; called by muse, mutect2
- TIAM1 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 291/603 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV54548401; called by muse, mutect2, varscan2
- TP53 | c.843_844dup p.R282Pfs*64 | Frame Shift Ins (INS) | VAF 68/677 reads (10%) | catalogued as COSV53688964; called by mutect2, pindel*, varscan2*
- AKAP6 | c.2683G>C p.A895P | Missense Mutation (SNP) | VAF 78/354 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH1 | c.8874G>A p.M2958I | Missense Mutation (SNP) | VAF 40/425 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.229); called by muse, mutect2
- EPHA5 | c.242del p.N81Mfs*24 | Frame Shift Del (DEL) | VAF 35/329 reads (11%) | called by mutect2, pindel, varscan2
- ZMIZ1 | c.701T>C p.I234T | Missense Mutation (SNP) | VAF 86/648 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF384 | c.1542_1568delinsACAGCCACCACCCTACATCCATCCG p.Q516Pfs*31 (on ENST00000361959; = p.Q455Pfs*31 on NM_133476.5) | Frame Shift Del (DEL) | VAF 42/254 reads (17%) | called by muse*, pindel
- ZNF384 | c.1516_1528delinsAT p.Q506Ifs*38 (on ENST00000361959; = p.Q445Ifs*38 on NM_133476.5) | Frame Shift Del (DEL) | VAF 84/347 reads (24%) | called by pindel, varscan2*
- FLG | c.12138G>T p.S4046= | Silent (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- IGHV3-43 | chr14:106470263 ins CGGAGAA | 3'Flank (INS) | VAF 19/111 reads (17%) | called by mutect2, pindel, varscan2
